Somatic mutation profile of tumor specimen MMRF_2834_1_BM_CD138pos (aliquot MMRF_2834_1_BM_CD138pos_T1_KHS5U_L16556) from MMRF case MMRF_2834, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2834_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06bde93c-6c64-4797-be65-c9ba51b9c0e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2834_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2834_1_PB_WBC_C2_KHS5U_L16603; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f67bfa0-9201-4dfe-9a04-80554f2d1978

The open-access MAF lists 61 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 3'UTR 19, Silent 5, Intron 5, 5'UTR 4, 5'Flank 3, Frame Shift Del 2, 3'Flank 1, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGLV2-23 | c.288C>G p.I96M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs376155748; called by muse, mutect2
- IGLV3-25 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 50/130 reads (38%) | catalogued as rs551428650; called by muse, varscan2
- IGLV3-25 | c.325G>C p.A109P | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs181874336; called by muse, mutect2, varscan2
- IGLV4-60 | c.166T>C p.W56R | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771795976; called by muse, mutect2, varscan2
- NLGN4X | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs751945904, CM057847, COSV52015100; called by muse, mutect2, varscan2
- NOTCH3 | c.4636C>T p.R1546C | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs774475688, COSV54628021; called by muse, mutect2, varscan2
- OBSCN | c.9547C>T p.R3183W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs376064010; called by muse, varscan2
- PIK3C2B | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.502); catalogued as rs146986563; called by muse, mutect2, varscan2
- SMG1 | c.6395C>T p.P2132L | Missense Mutation (SNP) | VAF 109/219 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs989012728; called by muse, mutect2, varscan2
- TRHDE | c.1628A>G p.H543R | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs752580387, COSV53833686; called by muse, mutect2, varscan2
- CCND1 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, varscan2
- CCND1 | c.133T>C p.F45L | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.087); called by muse, varscan2
- CPNE6 | c.243del p.F81Lfs*49 | Frame Shift Del (DEL) | VAF 19/31 reads (61%) | called by mutect2, pindel, varscan2
- CUL2 | c.303G>T p.M101I | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DDX60 | c.1114C>T p.L372F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- IGLV3-25 | c.135_152del p.L46_A51del | In Frame Del (DEL) | VAF 24/115 reads (21%) | called by pindel, varscan2
- NFKB1 | c.53A>G p.D18G | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR1D5 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5R1 | c.702A>C p.Q234H | Missense Mutation (SNP) | VAF 101/201 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ORMDL2 | c.258G>C p.W86C | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKCD | c.1301A>G p.D434G | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENT5C | c.551del p.F184Sfs*27 | Frame Shift Del (DEL) | VAF 46/123 reads (37%) | called by mutect2, pindel, varscan2
- TRAF3 | c.334dup p.A112Gfs*9 | Frame Shift Ins (INS) | VAF 42/75 reads (56%) | called by mutect2, pindel, varscan2
- UNC80 | c.7663A>T p.M2555L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); called by muse, mutect2
- AHSG | c.780A>G p.Q260= | Silent (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- CAP2 | c.741C>T p.F247= | Silent (SNP) | VAF 50/95 reads (53%) | catalogued as rs150167032; called by muse, mutect2, varscan2
- FAN1 | c.2829G>A p.V943= | Silent (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- FZD8 | c.831C>A p.T277= | Silent (SNP) | VAF 52/143 reads (36%) | called by muse, mutect2, varscan2
- RYR2 | c.1449G>A p.K483= | Silent (SNP) | VAF 61/124 reads (49%) | catalogued as COSV63662695, COSV63678957; called by muse, mutect2, varscan2
- ACSS3 | c.*1315T>A | 3'UTR (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.*971C>T | 3'UTR (SNP) | VAF 30/57 reads (53%) | catalogued as rs539084110; called by muse, mutect2, varscan2
- ADGRL3 | chr4:62071458 T>C | 3'Flank (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- ATP2B1 | c.-215A>G | 5'UTR (SNP) | VAF 48/95 reads (51%) | catalogued as rs1028339078; called by muse, mutect2, varscan2
- BCL7A | chr12:122021292 A>G | 5'Flank (SNP) | VAF 36/102 reads (35%) | called by muse, varscan2
- BCL7A | chr12:122021340 A>G | 5'Flank (SNP) | VAF 54/144 reads (38%) | called by muse, varscan2
- BCL7A | chr12:122021491 A>C | 5'Flank (SNP) | VAF 126/260 reads (48%) | called by muse, varscan2
- C2orf69 | c.*151G>T | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- CD4 | c.607+19C>T | Intron (SNP) | VAF 13/30 reads (43%) | catalogued as rs782301761; called by muse, mutect2, varscan2
- CRISPLD2 | c.1305+140G>A | Intron (SNP) | VAF 13/27 reads (48%) | catalogued as rs1387324203, COSV99295996; called by muse, mutect2
- CTSH | c.*714T>C | 3'UTR (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- DAOA | c.*112-143T>A | Intron (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- DTX1 | c.-308C>A | 5'UTR (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- DTX1 | c.-307C>T | 5'UTR (SNP) | VAF 38/87 reads (44%) | catalogued as COSV57496040; called by muse, mutect2, varscan2
- FEZ1 | c.*140G>A | 3'UTR (SNP) | VAF 47/139 reads (34%) | catalogued as COSV99630568; called by muse, mutect2, varscan2
- GNL3 | c.*188A>G | 3'UTR (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- HNRNPA1L2 | c.*311A>G | 3'UTR (SNP) | VAF 65/173 reads (38%) | called by muse, mutect2, varscan2
- ITGA5 | c.*687G>A | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- KIAA1755 | c.*975C>T | 3'UTR (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- LRATD2 | c.*1225T>C | 3'UTR (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- MAGEC2 | c.*177T>C | 3'UTR (SNP) | VAF 33/39 reads (85%) | catalogued as rs188818047; called by muse, mutect2, varscan2
- PATE2 | c.*164G>A | 3'UTR (SNP) | VAF 43/98 reads (44%) | catalogued as rs1020636944; called by muse, mutect2, varscan2
- PLBD2 | c.859+44G>A | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- PPARGC1B | c.*6237G>A | 3'UTR (SNP) | VAF 24/73 reads (33%) | catalogued as rs1316341712; called by muse, mutect2, varscan2
- RAB3GAP1 | c.*267A>G | 3'UTR (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- RNF214 | c.1236+46T>G | Intron (SNP) | VAF 54/129 reads (42%) | called by muse, mutect2, varscan2
- SETBP1 | c.*791G>A | 3'UTR (SNP) | VAF 31/66 reads (47%) | catalogued as rs1292406869; called by muse, mutect2, varscan2
- SKP1 | c.*20T>C | 3'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.*761_*762del | 3'UTR (DEL) | VAF 35/102 reads (34%) | called by pindel, varscan2
- UBE2E3 | c.*69C>G | 3'UTR (SNP) | VAF 70/195 reads (36%) | called by muse, mutect2, varscan2
- WDR91 | c.*1413del | 3'UTR (DEL) | VAF 57/146 reads (39%) | called by mutect2, pindel, varscan2
- ZNF280B | c.-35G>A | 5'UTR (SNP) | VAF 59/158 reads (37%) | called by muse, mutect2, varscan2
